Somatic mutation profile of tumor specimen TCGA-A6-5660-01A (aliquot TCGA-A6-5660-01A-01D-1650-10) from TCGA case TCGA-A6-5660, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 73.4 years (26,803 days).
Specimen TCGA-A6-5660-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70536361-d67a-40f3-964e-9bbb7e7f7c8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-5660-10A (Blood Derived Normal), aliquot TCGA-A6-5660-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b46d22a-6715-4508-9ce8-8fe6d3bc2370

The open-access MAF lists 136 somatic variants for this specimen: 102 protein-altering or splice-affecting, 34 silent.
By variant classification: Missense Mutation 87, Silent 34, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 2, In Frame Del 2, Splice Site 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 138/178 reads (78%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.529_546del p.P177_C182del | In Frame Del (DEL) | VAF 24/38 reads (63%) | hotspot (GDC flag); called by mutect2, varscan2
- A2M | c.3005C>A p.S1002Y | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV59386207; called by muse, mutect2
- ABTB1 | c.1132G>A p.E378K (on ENST00000232744 / NM_172027.3; = p.E236K on NM_032548.3) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs755880704, COSV51741165; called by muse, mutect2, varscan2
- ADAM21 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV50789103; called by muse, mutect2, varscan2
- ADAMTS3 | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 100/193 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99711919; called by muse, mutect2, varscan2
- AURKC | c.434C>T p.T145M (on ENST00000302804 / NM_001015878.2; = p.T111M on NM_003160.3) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as rs45503793, COSV57138405; called by muse, mutect2, varscan2
- BACH2 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs374916471; called by muse, mutect2, varscan2
- BAZ2B | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV58600302; called by muse, mutect2, varscan2
- BCAS3 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs377752373; called by muse, mutect2, varscan2
- C20orf194 | c.3016G>T p.G1006* | Nonsense Mutation (SNP) | VAF 62/157 reads (39%) | catalogued as COSV52695559, COSV52701462; called by muse, mutect2, varscan2
- CBX2 | c.1397G>A p.S466N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs1555831402, COSV53969015; called by muse, mutect2, varscan2
- CCDC102B | c.553A>G p.R185G | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV60136494; called by muse, mutect2
- CCDC178 | c.2251G>C p.D751H (on ENST00000383096 / NM_001105528.3; = p.D713H on NM_198995.3) | Missense Mutation (SNP) | VAF 128/354 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV55772731; called by muse, mutect2, varscan2
- CCDC39 | c.2546_2547insC p.T850Yfs*2 | Frame Shift Ins (INS) | VAF 48/230 reads (21%) | catalogued as COSV56483702; called by mutect2, pindel, varscan2
- CLGN | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 206/375 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756437881, COSV100346795; called by muse, mutect2, varscan2
- COL11A1 | c.5128T>G p.F1710V | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.266); catalogued as COSV62171941; called by muse, mutect2
- COL22A1 | c.2782G>A p.G928S | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1309497590, COSV57335778; called by muse, mutect2, varscan2
- CPS1 | c.3158T>A p.I1053N | Missense Mutation (SNP) | VAF 78/275 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99243950; called by muse, mutect2, varscan2
- CSMD1 | c.2782G>A p.D928N (on ENST00000520002; = p.D927N on NM_033225.6) | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779007112, COSV59320190; called by muse, mutect2
- CSPP1 | c.2371G>C p.E791Q (on ENST00000676605; = p.E750Q on NM_024790.6) | Missense Mutation (SNP) | VAF 34/631 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV99139737; called by muse, mutect2
- CTDP1 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99311051; called by muse, mutect2
- CUL9 | c.6704G>A p.R2235H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as rs975038563, COSV52728269; called by muse, mutect2, varscan2
- CYB561 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374915589; called by mutect2, varscan2
- CYP4F12 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs1442690573, COSV61173695; called by muse, mutect2, varscan2
- DEPDC7 | c.626G>A p.G209E (on ENST00000241051 / NM_001077242.2; = p.G200E on NM_139160.2) | Missense Mutation (SNP) | VAF 115/238 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.12); catalogued as COSV53807029, COSV99572558; called by muse, mutect2, varscan2
- DNAH17 | c.12970G>A p.G4324S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779260124, COSV53145151; called by mutect2, varscan2
- DOCK5 | c.4313C>T p.P1438L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs765162352, COSV99377727; called by muse, mutect2, varscan2
- DUSP13 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as rs997719084, COSV57814310; called by muse, mutect2, varscan2
- DYNC2H1 | c.9593C>A p.A3198D | Missense Mutation (SNP) | VAF 109/254 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV100519591; called by muse, mutect2, varscan2
- ELL3 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 41/53 reads (77%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as COSV100082670; called by muse, mutect2, varscan2
- EPHB1 | c.568C>A p.R190S | Missense Mutation (SNP) | VAF 376/738 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.369); catalogued as COSV67660891, COSV67662697; called by muse, varscan2
- FAM124B | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV66271951; called by muse, mutect2, varscan2
- FASN | c.4471G>T p.A1491S | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV60754359; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.421A>C p.T141P | Missense Mutation (SNP) | VAF 263/617 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.284); catalogued as COSV58553483; called by muse, mutect2, varscan2
- GNA12 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs758369709, COSV51740672; called by muse, mutect2, varscan2
- GPR27 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV55204280; called by muse, varscan2
- GRIA4 | c.2338G>A p.V780I | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs761018528, COSV56881287; called by muse, mutect2, varscan2
- HELZ2 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs745748003, COSV100915688; called by muse, mutect2, varscan2
- HLCS | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs150431185; called by muse, mutect2, varscan2
- HYDIN | c.14002G>A p.E4668K | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs972241458, COSV101125204; called by muse, varscan2
- IFT80 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100425094; called by muse, mutect2
- IGDCC4 | c.2503G>A p.G835S | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (1); PolyPhen possibly damaging (0.536); catalogued as rs202013326; called by muse, mutect2, varscan2
- IL12RB1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs142273743, COSV59097090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL13RA2 | c.1032C>G p.F344L | Missense Mutation (SNP) | VAF 110/412 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV54565091; called by muse, mutect2, varscan2
- JAKMIP1 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as rs1174209109, COSV51524627; called by muse, mutect2, varscan2
- KCNN2 | c.713C>T p.T238M (on ENST00000264773; = p.T450M on NM_021614.4) | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1383767398, COSV53288080; called by muse, mutect2, varscan2
- KCNQ2 | c.1149-1G>T p.X383_splice (on ENST00000359125 / NM_172107.4; = p.X373_splice on NM_004518.6) | Splice Site (SNP) | VAF 12/88 reads (14%) | catalogued as COSV60540450, COSV60544419; called by muse, mutect2, varscan2
- KCTD19 | c.2048C>T p.S683L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as COSV100431186; called by muse, mutect2, varscan2
- KIF1A | c.3298C>T p.R1100C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs752464745, COSV57488382; called by muse, mutect2, varscan2
- KIR2DL1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 52/353 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779537643, COSV52406976; called by muse, mutect2, varscan2
- KLHL14 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.959); catalogued as rs761029707, COSV63830813; called by muse, mutect2, varscan2
- KNTC1 | c.1622A>C p.E541A | Missense Mutation (SNP) | VAF 21/330 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100338737; called by muse, mutect2
- LAMP3 | c.901T>C p.Y301H | Missense Mutation (SNP) | VAF 110/213 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55614785; called by muse, mutect2, varscan2
- LYPD6 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776243056, COSV61940086; called by muse, mutect2, varscan2
- MINAR1 | c.966C>A p.D322E | Missense Mutation (SNP) | VAF 32/37 reads (86%) | SIFT tolerated (0.24); PolyPhen benign (0.307); catalogued as COSV59582811; called by muse, mutect2, varscan2
- MKRN3 | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV58809790, COSV58811645; called by muse, mutect2, varscan2
- MVP | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as rs779418542, COSV62421342; called by muse, mutect2, varscan2
- MYF6 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.143); catalogued as rs535543850, COSV57351541; called by muse, mutect2, varscan2
- MYH6 | c.2540C>T p.T847M | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.556); catalogued as rs759408374, COSV62447730; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NGFR | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.436); catalogued as rs764232409, COSV50802129; called by muse, mutect2, varscan2
- NRG3 | c.1097G>T p.C366F | Missense Mutation (SNP) | VAF 112/486 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV64543166; called by muse, mutect2, varscan2
- NRXN1 | c.2366G>C p.C789S | Missense Mutation (SNP) | VAF 96/357 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs200610894, COSV58450636, COSV58475590; called by muse, mutect2, varscan2
- OBI1 | c.425A>G p.K142R | Missense Mutation (SNP) | VAF 753/1707 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV56145521; called by muse, mutect2, varscan2
- OR10A7 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200112818, COSV58279205; called by muse, mutect2, varscan2
- OR5AS1 | c.617T>C p.I206T | Missense Mutation (SNP) | VAF 36/418 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV57981716; called by muse, mutect2
- OR5B21 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs534324656, COSV64481610; called by muse, mutect2, varscan2
- PIK3CA | c.2174A>G p.D725G | Missense Mutation (SNP) | VAF 244/458 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV55889334; called by muse, mutect2, varscan2
- PLCB1 | c.1250+1G>A p.X417_splice | Splice Site (SNP) | VAF 49/204 reads (24%) | catalogued as rs1464666472, COSV62049464; called by muse, mutect2, varscan2
- PLPPR5 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99587830; called by muse, mutect2, varscan2
- PLVAP | c.41C>A p.A14E | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV99391812; called by muse, mutect2, varscan2
- POU2F2 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); catalogued as COSV60762504; called by muse, mutect2, varscan2
- PTPRO | c.557G>T p.C186F | Missense Mutation (SNP) | VAF 18/477 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55526212; called by muse, mutect2
- RALYL | c.280A>G p.K94E | Missense Mutation (SNP) | VAF 270/368 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV72820465; called by muse, varscan2
- REV3L | c.9067C>G p.R3023G | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV62618360, COSV62618648; called by muse, mutect2, varscan2
- RNF169 | c.1676T>G p.L559* | Nonsense Mutation (SNP) | VAF 43/99 reads (43%) | catalogued as COSV55132331; called by muse, mutect2, varscan2
- SLC4A8 | c.1327C>A p.P443T | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV60651823; called by muse, mutect2, varscan2
- SRRM4 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as rs766052804, COSV57415519; called by muse, mutect2, varscan2
- SUCO | c.2222T>C p.I741T | Missense Mutation (SNP) | VAF 81/138 reads (59%) | SIFT tolerated (0.38); PolyPhen benign (0.051); catalogued as COSV55264894; called by muse, mutect2, varscan2
- SYNDIG1 | c.407T>A p.L136H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as COSV65234737; called by muse, mutect2
- TBC1D22A | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 177/323 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV61438712; called by muse, mutect2, varscan2
- TFAP2B | c.640A>G p.N214D | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV53827600; called by muse, mutect2, varscan2
- TMPRSS2 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as rs757262240, COSV59823167; called by muse, mutect2, varscan2
- TRDN | c.1050del p.E351Sfs*13 | Frame Shift Del (DEL) | VAF 58/234 reads (25%) | catalogued as rs753514580; called by mutect2, varscan2
- TRMT61B | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs760677287, COSV100066780; called by muse, mutect2, varscan2
- TRPM5 | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs768526088, COSV99330497; called by muse, mutect2, varscan2
- TRPV6 | c.893A>G p.H298R | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV100844416; called by muse, mutect2, varscan2
- USH2A | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as COSV56365784; called by muse, mutect2, varscan2
- USP9X | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 402/473 reads (85%) | catalogued as COSV100200018; called by muse, mutect2, varscan2
- VSIG10 | c.568C>A p.L190M | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.755); catalogued as rs754405924, COSV100821349; called by muse, mutect2
- VSX2 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs777493485, COSV100001830, COSV56217253; called by muse, mutect2, varscan2
- WDR24 | c.364G>A p.V122M (on ENST00000248142; = p.V60M on NM_032259.4) | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.793); catalogued as rs376830909; called by muse, mutect2, varscan2
- YTHDF1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.407); catalogued as rs373868224; called by muse, mutect2, varscan2
- ZNF10 | c.1286G>C p.G429A | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV99940147; called by muse, mutect2
- ZNF423 | c.2285C>T p.A762V (on ENST00000563137 / NM_001379286.1; = p.A754V on NM_015069.4) | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV52187626; called by muse, mutect2, varscan2
- ZNF680 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 96/650 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.108); catalogued as COSV59015287; called by muse, mutect2, varscan2
- ADH1C | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.058); called by muse, mutect2
- LRRC41 | c.1300dup p.E434Gfs*70 | Frame Shift Ins (INS) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- MYC | c.793_795del p.V265del (on ENST00000377970; = p.V280del on NM_002467.6) | In Frame Del (DEL) | VAF 42/263 reads (16%) | called by pindel, varscan2
- NKIRAS1 | c.230_232dup p.S77dup | In Frame Ins (INS) | VAF 86/325 reads (26%) | called by mutect2, pindel, varscan2
- PAPPA | c.4463_4464del p.L1488Qfs*6 | Frame Shift Del (DEL) | VAF 89/131 reads (68%) | called by mutect2, pindel, varscan2
- ZNF292 | c.5162del p.L1721* | Frame Shift Del (DEL) | VAF 23/117 reads (20%) | called by mutect2, pindel, varscan2
- ABCC4 | c.1314C>T p.G438= | Silent (SNP) | VAF 52/204 reads (25%) | catalogued as rs150945397; called by muse, mutect2, varscan2
- ACVR2B | c.930C>T p.G310= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs200335360; called by muse, mutect2, varscan2
- AKAP8L | c.1233G>A p.K411= | Silent (SNP) | VAF 77/137 reads (56%) | catalogued as rs775271699, COSV101275862; called by muse, mutect2, varscan2
- AMER2 | c.1389G>A p.A463= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV100766371; called by muse, mutect2, varscan2
- BFSP2 | c.1212C>G p.S404= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV56586632, COSV56588678; called by muse, mutect2
- CD3E | c.588G>A p.R196= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV62345714; called by muse, mutect2, varscan2
- CD99 | c.258C>T p.S86= | Silent (SNP) | VAF 299/917 reads (33%) | catalogued as rs1227133906, COSV101153077, COSV101153303; called by muse, mutect2, varscan2
- CDYL2 | c.879C>T p.D293= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as rs767400567, COSV73653805; called by muse, mutect2, varscan2
- CHST1 | c.423G>A p.P141= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs1437246280, COSV57321507, COSV57323443; called by muse, mutect2, varscan2
- CSMD3 | c.8211C>T p.I2737= | Silent (SNP) | VAF 385/514 reads (75%) | catalogued as rs141863300; called by muse, mutect2, varscan2
- CXADR | c.748C>T p.L250= | Silent (SNP) | VAF 187/708 reads (26%) | catalogued as COSV99515625; called by muse, mutect2, varscan2
- CXXC1 | c.840A>C p.S280= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV53274432; called by muse, mutect2
- ENTPD7 | c.1551C>T p.A517= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV65112265; called by muse, mutect2, varscan2
- FGF13 | c.630C>T p.H210= | Silent (SNP) | VAF 65/73 reads (89%) | catalogued as rs1213374199, COSV59545405; called by muse, mutect2, varscan2
- FHL5 | c.834C>T p.S278= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs758026961, COSV58737373; called by muse, mutect2, varscan2
- HM13 | c.489G>C p.L163= | Silent (SNP) | VAF 63/310 reads (20%) | catalogued as COSV59437050; called by muse, mutect2
- IGHV1-45 | c.237C>T p.Y79= | Silent (SNP) | VAF 31/204 reads (15%) | catalogued as rs191537967; called by muse, mutect2, varscan2
- LAMC3 | c.846C>T p.P282= | Silent (SNP) | VAF 55/67 reads (82%) | catalogued as rs763182921, COSV63089889; called by muse, mutect2, varscan2
- LRP5 | c.3126C>T p.C1042= | Silent (SNP) | VAF 43/76 reads (57%) | catalogued as rs773523178, COSV53715315; called by muse, varscan2
- LY6H | c.183C>T p.S61= | Silent (SNP) | VAF 160/199 reads (80%) | catalogued as rs1212681301, COSV100713939; called by muse, mutect2, varscan2
- MYO9A | c.1167G>A p.T389= | Silent (SNP) | VAF 171/243 reads (70%) | catalogued as rs1286402096, COSV61850645; called by muse, mutect2, varscan2
- OR6B2 | c.144C>T p.I48= | Silent (SNP) | VAF 114/223 reads (51%) | catalogued as rs142836659, COSV53154275; called by muse, mutect2, varscan2
- PLXNC1 | c.1416C>T p.C472= | Silent (SNP) | VAF 72/159 reads (45%) | catalogued as rs745637999, COSV51574892; called by muse, mutect2, varscan2
- SERBP1 | c.690A>G p.E230= (on ENST00000370995 / NM_001018067.2; = p.E224= on NM_015640.4) | Silent (SNP) | VAF 105/314 reads (33%) | catalogued as rs570477386, COSV100769162; called by muse, mutect2, varscan2
- SLC10A2 | c.903C>T p.A301= | Silent (SNP) | VAF 82/182 reads (45%) | catalogued as rs199679714; called by muse, mutect2, varscan2
- SLC25A48 | c.168C>T p.F56= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as rs755946082, COSV50848839; called by muse, mutect2, varscan2
- SLIT3 | c.3645G>A p.L1215= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV60606997; called by muse, mutect2, varscan2
- STAG3 | c.642C>T p.D214= | Silent (SNP) | VAF 20/265 reads (8%) | catalogued as rs1412311710, COSV100426162; called by muse, mutect2
- STK33 | c.930C>T p.G310= | Silent (SNP) | VAF 65/231 reads (28%) | catalogued as rs531828477, COSV59395745; called by muse, mutect2, varscan2
- TRIM67 | c.2238C>T p.H746= | Silent (SNP) | VAF 53/149 reads (36%) | catalogued as rs969053608, COSV64158784; called by muse, mutect2, varscan2
- TRPV6 | c.1494C>T p.L498= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs900977918, COSV63891705; called by muse, mutect2, varscan2
- TTBK1 | c.1395G>A p.A465= | Silent (SNP) | VAF 53/90 reads (59%) | catalogued as rs1020539443, COSV52490995; called by muse, mutect2, varscan2
- ULK1 | c.2970G>A p.S990= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs751454599, COSV58856402; called by muse, varscan2
- UNC5CL | c.1246C>T p.L416= | Silent (SNP) | VAF 101/170 reads (59%) | catalogued as COSV55109894; called by muse, mutect2, varscan2
